TCGA case TCGA-MQ-A6BS — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/50921ca1-5d70-4162-8847-74e874114284

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Dead; Days to death: 608 days (1.7 years).

Diagnoses (2)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 55.8 years (20,384 days); Year of diagnosis: 2012; Method of diagnosis: Imaging; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 608 days (1.7 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Antineoplastic Vaccine; Days to treatment start: 151 days; Days to treatment end: 243 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment end: 96 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed; Days to treatment end: 96 days.
   Treatment given: Treatment type: Pleurodesis, NOS; Timepoint category: Prior to Procurement.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tissue or organ of origin: Thorax, NOS; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 56.7 years (20,716 days); Days to diagnosis: 332 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 332 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Thorax, NOS.
- Days to follow up: 414 days (1.1 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 608.

Exposures
- Exposure type: Asbestos; Exposure source: Occupational.
- Occupation duration years: 20; Occupation type: Building Frame and Related Trades Workers.

Family history
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Brain Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MQ-A6BS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 260 mg.
  Slide TCGA-MQ-A6BS-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-MQ-A6BS-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-MQ-A6BS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: Yes; Pleurodesis performed 90 days: No; Tumor status: Tumor free; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Worked in a brick yard; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma; Mesothelioma detection method: Thorascopy.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event site other: Ipsilateral Chest Cavity.
- Drug treatment 3: Pharmaceutical therapy drug name: WT-1 Vaccine.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 608 days; disease-specific survival: no event (censored), 608 days; disease-free interval: no event (censored), 608 days; progression-free interval: no event (censored), 608 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MQ-A6BS-01A-12D-A34B-01): tumor purity 0.78, ploidy 2.61, whole-genome doublings 1.
